Surgical pathology report (de-identified scan), TCGA case TCGA-IB-AAUQ, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-AAUQ-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
Copied To		Location	

Report Patient Name:
Demographics (for verification purposes)
Sex: M

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
A. Liver biopsy at
B. Liver biopsy number 2 at
C. Liver biopsy number 3 at
D. Body and tail of pancreas at
Clinical Information
Pancreatitis. Possible pancreatic cancer.

ICD O-3
Adenocarcinoma, duct NOS
8500/3
Site: Pancreas tail
C25.2
JW 5/20/14

Diagnosis

- A. Liver, Biopsy:
- Bile duct hamartoma.
- Negative for malignancy.
- B. Liver, Biopsy #2:
- Benign liver tissue.
- Negative for malignancy.
- C. Liver, Biopsy #3:
- Benign liver tissue.
- Negative for malignancy.
- D. Pancreas, Body and Tail, Distal Pancreatectomy:
- Invasive ductal adenocarcinoma, moderately differentiated with focal foamy gland pattern, 4.5 x 3.5 x 3.5 cm.
- Prominent perineural, lymphatic, and venous invasion present.
- Invasive adenocarcinoma involves retroperitoneal margin and pancreatic body margin.
- Thirteen of twenty-one peripancreatic lymph nodes involved by metastatic adenocarcinoma (13/21); extranodal extension present; largest tumor deposit 1.2 cm.
- Please see comment and synoptic report.

Reported by:

Electronically signed by:

Verified:

Synoptic Report

SPECIMEN:

Body of pancreas

Tail of pancreas

PROCEDURE:

Partial pancreatectomy, pancreatic tail

TUMOR SITE:

[page 2 of 3]
Pancreatic tail
TUMOR SIZE:
Greatest dimension: 4.5 cm
Additional dimensions: 3.5 x 3.5 cm
HISTOLOGIC TYPE:
Ductal adenocarcinoma
HISTOLOGIC GRADE:
G2: Moderately differentiated
MICROSCOPIC TUMOR EXTENSION:
Tumor invades peripancreatic soft tissues
Tumor invades retroperitoneal soft tissue
Tumor invades other adjacent organs or structures:
tumor invades wall of splenic vein
MARGINS:
Margin(s) involved by invasive carcinoma
Proximal pancreatic margin
Invasive carcinoma involves posterior retroperitoneal surface of pancreas
TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):
No prior treatment
LYMPH-VASCULAR INVASION:
Present
PERINEURAL INVASION:
Present
PRIMARY TUMOR (pT):
pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery
REGIONAL LYMPH NODES (pN):
pN1: Regional lymph node metastasis
Number examined: 21
Number involved: 13
DISTANT METASTASIS (pM):
Not applicable
ADDITIONAL PATHOLOGIC FINDINGS:
Pancreatic intraepithelial neoplasia (highest grade: PanIN 2)
Chronic pancreatitis
Gross Description
Received are specimen containers A to D. All requisitions and specimen containers are labelled with the patient's name, The cassettes and identifiers are labelled with the Surgical Number
A. The specimen consists of liver tissue, measuring 0.3 cm. Submitted in toto in one cassette.
The specimen is received fresh and is subsequently placed into formalin. The container is designated "A: Liver biopsy at . The previously frozen tissue is entirely resubmitted for permanent sections in cassette AQS1.
B. The specimen consists of liver tissue, measuring 0.2 cm. Submitted in toto in one cassette.
The specimen is received fresh and is subsequently placed into formalin. The container is designated "B: Liver biopsy number 2 at . The previously frozen tissue is entirely resubmitted for permanent sections in cassette BQS1.
C. The specimen consists of liver tissue, measuring 0.8 cm. Submitted in toto in one cassette.
The specimen is received fresh and is subsequently placed into formalin. The container is designated "C: Liver biopsy number 3 at . The previously frozen tissue is entirely submitted for permanent sections in cassette CQS1.
D. The specimen is received fresh and is subsequently placed into formalin. The container is designated "D: Body and tail of pancreas at , and contains a 12.0 x 6.0 x 3.5 cm portion of pancreatic body and tail. The pancreatic body margin is inked blue, the distal margin is inked orange, and the radial margin is inked black. The specimen is bisected longitudinally and is fixed in formalin overnight. Sectioning reveals an ill-defined, firm, yellow-tan, 4.5 x 3.5 x 3.5 cm mass with a few punctate hemorrhagic areas. The mass is located in the anterior half of the specimen and grossly extends to the anterior serosa, to within 1.0 cm of the blue-inked pancreatic body resection margin, and very close (1-2 mm) to the posterior/retroperitoneal margin. The rim of pancreatic tissue proximal to the mass is soft and tan-colored with a normal lobular configuration. The pancreatic tail tissue distal to the mass (3.5 x 1.0 cm) is attenuated, faintly nodular, and atrophic-appearing. The pancreatic duct passes through the central posterior aspect of the mass, and shows no obvious dilation, stricture, or intraductal mass. Within the peripancreatic fat superior, inferior and posterior to the mass, there are multiple well-circumscribed ovoid, firm, white nodules, consistent with lymph nodes, many of which appear grossly suspicious for metastatic tumor. Representative sections are submitted as follows:

[page 3 of 3]
- D1. representative perpendicular section of pancreatic body margin closest to tumor
- D2/3. remainder of pancreatic body margin, shaved and submitted en face
- D4. single grossly suspicious lymph node, superior to pancreatic mass, sectioned
- D5. additional superior margin with possible lymph nodes
- D6. single grossly suspicious lymph node located superior to mass, bisected
- D7 to 9. additional representative sections of superior portion of tumor with adjacent grossly positive lymph nodes
- D10 to 12. representative sections of tumor with retroperitoneal margin and grossly suspicious retroperitoneal lymph nodes
- D13. representative section of atrophic pancreatic tail near retroperitoneum
- D14. representative portion of central tumor with large vessel
- D15/16. tumor with inferior margin
- D17. representative portion of atrophic distal pancreatic tail with distal margin
- D18. distal portion of tumor with adjacent possible lymph node
- D19. tumor with adjacent anterior serosa
- D20. distal peripancreatic fat with three possible lymph nodes (bisected)
- D21. two additional possible lymph nodes

Frozen Section Diagnosis

A. Liver Biopsy:

- No evidence of carcinoma.

B. Liver Biopsy Number 2:

- Negative for malignancy.

C. Liver Biopsy Number 3:

- Negative for carcinoma.

Reported by:

Pathologist Comment

In case ancillary studies are desired, tumor block information is listed below:

Best tumor block: D4

Best normal block: D17

Accession Number
Encounter Number
Patient Location

Source: NCI Genomic Data Commons file d39577ac-0110-4b0e-aeb1-e0ebf55e8c85 (TCGA-IB-AAUQ.B2B5526A-ADC6-4F65-B5B2-6B0E895968FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).